Surgical pathology report (de-identified scan), TCGA case TCGA-2F-A9KP, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Erasmus MC, specimen TCGA-2F-A9KP-01A (Primary Tumor).

Pathology report

Date of tumor procurement

Date of report

Histologic diagnosis

High grade muscle invasive urothelial cell carcinoma, T3aN2Mx

Anatomic site and laterality

Right dorsolateral bladder wall

Tumor size

3.5cm diameter

Lymph node status

A total of 21 lymph nodes, in 2 right iliac lymph nodes metastasis of urothelial cell carcinoma (0.8cm + 1cm) with extra-nodal growth

ICD-O-3

Carcinoma, urothelial NOS
Site: ^{C67.2} Bladder, lateral wall
^{C67.2} Bladder, overlapping lesion C67.8
11/29/14

Source: NCI Genomic Data Commons file d865553f-ff93-4f76-92da-2c990deae13f (TCGA-2F-A9KP.19580F74-7FD9-4366-9FFB-D66D2BC33336.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).